Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A7WF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A7WF-01A (Primary Tumor).

[page 1 of 4]
Patient:
Hospital No:
Date Of Birth:
Age Sex:
Location:

Path #:
Pathologist:
Assistant:
Date of Procedure:
Date Received:

Ordering M.D.:

Copies To:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. UTERUS AND CERVIX, RADICAL HYSTERECTOMY:

- Primary cervical adenosquamous carcinoma
- Histologic grade: Poorly-differentiated, grade III/III
- Tumor size: The tumor is circumferential measuring 5.0 cm in diameter x 3.0 cm in length
- Depth of stromal invasion: 0.68%
- The maximum thickness of stromal invasion is 13.0 mm
- The thickness of the cervix in the area of maximal stromal invasion is 19.0 mm
- Staging Information: pT1b2 N0 Mx
- Foci of adenocarcinoma in situ present adjacent to foci of invasive carcinoma
- Foci consistent with lymphovascular space invasion present
- No vaginal extension is identified
- The tumor does not extend into uterine corpus
- No parametrial involvement is identified
- All surgical margins are free from involvement (deep cervical, vaginal, parametrial)
- The endometrium is secretory
- The myometrium is unremarkable

B. LEFT OVARY AND FALLOPIAN TUBE, LEFT SALPINGO-OOPHORECTOMY:

- Left ovary showing follicles and surface adenofibromatous change
- Left fallopian tube showing no significant histopathologic changes
- No malignancy identified

C. RIGHT OVARY AND FALLOPIAN TUBE, RIGHT SALPINGO-OOPHORECTOMY:

- Right ovary showing follicles, corpus luteum and surface adhesions
- Right fallopian tube showing no significant histopathologic changes
- No malignancy identified

D. RIGHT PELVIC LYMPH NODE, EXCISION:

- No tumor identified in four lymph nodes (0/4)

E. RIGHT OBTURATOR NODE, EXCISION:

- No tumor identified in eight lymph nodes (0/8)

F. RIGHT PERIAORTIC NODE, BIOPSY:

- No tumor identified in two lymph nodes (0/2)

G. LEFT PELVIC LYMPH NODE, EXCISION:

- No tumor identified in four lymph nodes (0/4)

Patient Case(s).

ICD O-3
Carcinoma, adenosquamous
08560/13
Site Cervix NOS
C53.9
JW 11/12/13

[page 2 of 4]
PATIENT:

PATH #:

H. LEFT OBTURATOR NODE, EXCISION:

- No tumor identified in three lymph nodes (0/3)

I. LEFT PERIAORTIC LYMPH NODE, EXCISION:

- No tumor identified in two lymph nodes (0/2)

J. APPENDIX, APPENDECTOMY:

- Reactive lymphoid hyperplasia
- No malignancy identified

NOTE: Pancytokeratin immunostain performed on all lymph node specimens (B-I) is negative. Synaptophysin and chromogranin performed on blocks A9 (section of the tumor) are uniformly negative.

HISTORY: Cervical cancer

MICROSCOPIC:

See diagnosis.

GROSS:

A. UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus and cervix", and received in formalin is a symmetric 135 gram total abdominal hysterectomy specimen without bilateral adnexa which measures 9.0 cm from fundus to ectocervix, 6.0 cm from cornu to cornu and 3.7 cm from anterior to posterior. The serosal surface is tan-pink smooth and glistening without gross pathologic lesion. There is a large firm fungating mass with heaped edges involving the entire circumference of the cervix and invading along the endocervical canal which measures in total length 3.0 cm, in total diameter 5.0 cm and it is difficult to measure the maximal thickness. There is a rim of vaginal cuff extending 2.0 cm from the posterior margin of the cervix and 1.5 cm from the anterior margin of the cervix which has been previously inked blue on the anterior and black on the posterior surface. The endometrium measures from fundus to the edge of the fungating mass on the ectocervix, 7.0 cm x 4.0 cm. The endocervical canal has a maximum length of 5.0 cm. The endometrium demonstrates a smooth, firm tan-white mucosa without gross pathologic lesion. The endocervical canal, transformation zone and entire cervix appears to be involved by the tumor. The endometrium measures a maximum thickness of a 0.2 cm, and the myometrium demonstrates a maximal thickness of 1.7 cm. Sectioning of the anterior portion of the cervix demonstrates a fungating tumor that appears to involve slightly greater than 50% of the cervical wall but does not penetrate through to the serosal surface. Sectioning of the anterior corpus demonstrates a homogeneous tan-pink parenchyma without gross pathologic lesion. Sectioning of the posterior cervix demonstrates a firm, friable tan-white mass involving approximately slightly greater than 50% of the thickness of the cervix. Sectioning of the posterior corpus demonstrates a homogeneous firm tan-white parenchyma without gross pathologic lesion. Representative sections are submitted.

A1, A2. Anterior cervix, tumor, bisected - 1 each

A3. Anterior cervix, tumor - 1

A4, A5. Anterior cervix, tumor, bisected - 1 each

A6, A7. Anterior lower uterine segment, bisected - 1 each

A8. Anterior corpus - 1

A9, A10. Posterior cervix, tumor, bisected - 1 each

A11, A12. Posterior cervix, tumor, bisected - 1 each

A13, A14. Posterior cervix, tumor, bisected - 1 each

A15. Posterior corpus - 1

A16. Posterior lower uterine segment - 1

B. LEFT OVARY AND FALLOPIAN TUBE

Labeled with the patient's name, labeled "left ovary and fallopian tube", and received in formalin is an intact fallopian tube and ovary which measure 5.7 cm in length x 0.6 x 0.6 cm, and 3.4 x 2.5 x 1.1 cm, respectively. There is minimal attached ovarian adnexal tissue. The external surface of the ovary demonstrates a tan-white gyrate

[page 3 of 4]
PATIENT:**PATH #:**

surface without gross pathologic lesion. Upon sectioning the ovary demonstrates three cystic lesions and a firm white corpora albicantia and is otherwise free of gross pathologic lesion. These cysts measures 0.3 x 0.3 cm, 0.6 x 0.6 cm, and 0.9 x 0.7 cm. Sectioning of the fallopian tube demonstrates a patent stellate lumen with a maximum dimension of 0.2 cm. Representative sections are submitted.

B1. Ovary - 1

B2. Fallopian tube - 3

C. RIGHT OVARY AND FALLOPIAN TUBE

Labeled with the patient's name, labeled "right ovary and fallopian tube", and received in formalin is an intact fallopian tube and ovary which measure 6.5 cm in length x 0.6 x 0.6 cm, and 3.1 x 3.0 x 2.1 cm, respectively. The external surface of the ovary demonstrates multiple red-brown discolored, (likely hemorrhagic) cystic structures and a firm white gyrate appearance. Upon sectioning the ovary demonstrates multiple smooth-walled cystic structures one filled with red-brown viscous material (chocolate cyst) which measures 1.0 x 1.0 cm. The remainder of the cysts are smooth-walled and have a thin translucent fluid within their lumens and which range in size from 0.4 x 0.4 cm to 0.6 x 0.4 cm, 0.7 x 0.7 cm, and 0.1 x 0.1 cm. Representative sections.

C1. Ovary

C2. Fallopian tube

D. RIGHT PELVIC NODE

Labeled with the patient's name, labeled "right pelvic node", and received in formalin is a fragment of tan-yellow fibroadipose tissue. Multiple variable sized lymph nodes are identified varying in size from 0.3 cm to the largest measuring 1.6 cm. Entirely submitted.

D1. 1

E. RIGHT OBTURATOR NODE

Labeled with the patient's name, labeled "right obturator node", and received in formalin is a single portion of tan-yellow fibroadipose tissue with small possible lymph nodes varying in size from 0.2 up to 0.6 cm. Entirely submitted.

E1. 1

F. RIGHT PERIAORTIC NODE

Labeled with the patient's name, labeled "right periaortic node", and received in formalin are two fragments of tan-yellow fibroadipose tissue each containing a single lymph node which measure 0.6 x 0.4 x 0.3 cm and 0.6 x 0.4 x 0.3 cm. The specimen is entirely submitted.

F1. 2

G. LEFT PELVIC NODE

Labeled with the patient's name, labeled "left pelvic node", and received in formalin is a single fragment of soft yellow lobulated adipose tissue and tan-white fibroconnective tissue admixed with three soft brown lymph nodes measuring 0.6 cm, 0.7 cm and 1.0 cm in greatest dimension each. Entirely submitted.

G1. 1

H. LEFT OBTURATOR NODE

Labeled with the patient's name, labeled "left obturator node", and received in formalin is a single fragment of soft yellow lobulated adipose tissue with a single identified lymph node which measures 2.5 cm in greatest dimension. The specimen is entirely submitted.

H1. 1

I. LEFT PERIAORTIC NODE

Labeled with the patient's name, labeled "left periaortic node", and received in formalin are two fragments of soft yellow lobulated adipose tissue which each contain a single lymph node and which measure 0.9 x 0.6 x 0.4 cm and 0.9 x 0.6 x 0.2 cm. The specimen is entirely submitted.

I1. 2

[page 4 of 4]
PATIENT:

PATH #:

J. APPENDIX

Labeled with the patient's name, labeled "appendix", and received in formalin is an intact vermiform appendix measures 6.2 x 0.6 x 0.6 cm and which has a moderate amount of attached periappendiceal fat which extends 2.2 cm from the external surface of the specimen. The external surface is tan-pink smooth and glistening without pathologic lesion. Sectioning of the specimen demonstrates a patent stellate lumen measuring 0.2 cm in maximal dimension. Representative sections are submitted.

J1. Proximal, mid and distal appendix - 3

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

GROSS (CX-UX):

- Cx tumor circumferential extending to endocervix and probably to lower uterine segment
- Vaginal mucosa and cervix soft tissues grossly free of tumor margin (portion of tumor collected for research)

SPECIMEN D (RIGHT PELVIC LYMPH NODE):

- Negative for tumor

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Those immunohistochemical tests have not been cleared or approved by the

U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file f31c51d5-53ff-41e4-b85c-dc731200921f (TCGA-DS-A7WF.0C2D7B64-5F80-4F95-BCFC-D550A9674A2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).